Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A3NA, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A3NA-01A (Primary Tumor).

[page 1 of 3]
Sample #

Gender: Male

DOB:

Race:

Report Date:

hw 1/2/12	Yes	No
Criteria		
Review Initials	hw	hw

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- Pelvic lymph nodes, right, dissection:
- Twelve lymph nodes, no evidence of tumor (0/12).
- Pelvic lymph nodes, left; dissection:
- Eight lymph nodes, no evidence of tumor (0/8).
- Prostate and bladder; radical cystectomy:
- Invasive urothelial carcinoma; see pathologic parameters below.
- Prostatic adenocarcinoma; see pathologic parameters below.
- Sixty-five lymph nodes, no evidence of tumor.

ICB-0-3
carcinoma, urothelial, NOS 8/20/3
Path Site: bladder, NOS C67.9
CQUF bladder, well, posterior C67.4

hw 1/2/12

Urothelial Carcinoma Pathologic Parameters

- Tumor type: Urothelial carcinoma.
- Grade of tumor: High-grade.
- Depth of invasion: Muscularis propria, outer half.
- Tumor distribution: Solitary, 6.3 x 5.1 x 5.0 cm (depth); posterior wall.
- Ureteral Margins: Negative.
- Distal urethral margin: Negative.
- Lymph nodes: No carcinoma in 85 regional lymph nodes (0/85).
- pTNM: pT2b, N0, MX.

Radical Prostatectomy Pathologic Parameters

- Gleason Score: 3+4 = 7/10.
- Perineural Invasion: Absent.
- Tumor Location: Peripheral zone right.
- Tumor Volume Estimate: <5%.
- High-grade P.I.N.: Multifocal.
- Seminal Vesicles: Negative for tumor.
- Fibromuscular Capsule: Tumor confined to the prostate.
- Peripheral Margin: Positive for tumor (C16).
- Distal (apical) Margin: Negative for tumor.
- Proximal (basilar) Margin: Negative for tumor.
- Regional Lymph Nodes (right and left): Negative for tumor.
- pTNM: pT2a, N0, MX.

xxx

[page 2 of 3]
[] M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident or Fellow.

Electronically Signed Out by [] M.D.

Clinical History:

The patient is a -year-old male with a history of bladder tumor. Bladder washing showed urothelial carcinoma. The patient underwent radical cystectomy and neobladder.

Specimens Received:

A: Right pelvic lymph node

B: Left pelvic lymph node

C: Prostate & bladder

Gross Description:

The specimen is received in three containers each labeled with the patient's name and medical record number.

A. Container A is further designated 31. right pelvic lymph node⁴. Received fresh and placed in formalin are fragments of yellow-brown lobulated adipose tissue measuring 8.5 x 6 x 1.2 cm aggregate. Multiple firm rubbery lymph node candidates are dissected from the specimen ranging from 0.2-5.5 cm in greatest dimension. Representative sections are submitted as follows:

A1-A3: multiple lymph node candidates

A4-A6: one matted lymph node candidate

B. Container B is further designated 32. left pelvic lymph node⁴. Received fresh and placed in formalin are multiple fragments of yellow-brown adipose tissue measuring 6.5 x 5.5 x 2.0 cm in aggregate. Multiple yellow-brown firm-rubbery lymph node candidates are dissected from the specimen ranging from 0.2-4.0 cm in greatest dimension. Representative sections are submitted as follows:

B1-B3: multiple lymph node candidates

B4,B5: one matted lymph node candidate, bisected

C. Container C is further designated 33. bladder and prostate⁴. Received fresh and placed in formalin is a specimen of cystectomy weighing 395 gm and the overall measurement is 14.5 x 10.5 x 6.0 cm. The bladder measures 9.0 x 8.5 x 5.5 cm and the prostate measures 4.0 x 3.3 x 3.0 cm. The bladder is opened from the anterior wall with a Y-shaped incision. A gray-white, firm, ulcerated mass is identified in the posterior wall of the bladder measuring 6.3 x 5.1 cm and raised 2.8 cm from the bladder mucosa. Multiple small papillae are identified in the periphery of the mass. The outer surface of the bladder and the prostate is inked black on the left side and blue on the right side. Probing through the ureters reveals that both ureteral orifices are involved by the tumor. The specimen is serially sectioned. Both ureters are surrounded by solid tumor. The tumor displays a thickness of 5.0 cm. The tumor grossly invades through the bladder wall but not through the surrounding adipose tissue. The center of the tumor is white and soft and grossly necrotic. The prostate and the seminal vesicles are not grossly invaded by tumor. No lymph nodes are identified in the peri-bladder adipose tissue. Received in the same container is a 4.8 cm round tubular tissue with a diameter of 0.4 cm. Representative sections are submitted

[page 3 of 3]
as follows:

C1: urethral margin

C2: ureter margin

C3,C4: sections through the right ureter

C5,C6: sections through the left ureter

C7,C8: representative sections of tumor showing deepest invasion

C9-C11: representative sections of the tumor C12: normal bladder and
sections of the detached tubular structure

C13-C27: the entire prostate

C28: Seminal vesicles

C29, C30: representative sections of tumor

xxx

[] M.D. PhD

Source: NCI Genomic Data Commons file 30a67c8d-4982-4957-84b7-dde9e6dbbdf8 (TCGA-FD-A3NA.D738C31B-26D6-4B68-ABFE-01E6FE6A4F55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).